Somatic mutation profile of tumor specimen MMRF_1637_1_BM_CD138pos (aliquot MMRF_1637_1_BM_CD138pos_T1_KBS5U_L04308) from MMRF case MMRF_1637, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.3 years (23,473 days).
Specimen MMRF_1637_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd3ba4d0-ca95-4f5c-8c43-075f8ef4e751.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1637_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1637_1_PB_Whole_C3_KBS5U_L04319; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bed6c630-ac15-4835-bf57-a5b39f2eb022

The open-access MAF lists 230 somatic variants for this specimen: 84 protein-altering or splice-affecting, 24 silent, 122 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, 3'UTR 67, Intron 29, Silent 24, 5'UTR 14, 5'Flank 5, 3'Flank 5, RNA 2, Frame Shift Ins 1, Frame Shift Del 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AATK | c.1750G>A p.V584I (on ENST00000326724 / NM_001080395.3; = p.V481I on NM_004920.2) | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1465709672, COSV58365054; called by muse, mutect2, varscan2
- APC2 | c.6794G>A p.S2265N | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1378771163; called by muse, mutect2, varscan2
- APOB | c.3415G>A p.A1139T | Missense Mutation (SNP) | VAF 56/57 reads (98%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs778822926, COSV51923307; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARHGEF2 | c.521C>T p.S174F (on ENST00000361247 / NM_001162383.2; = p.S147F on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/130 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58114840; called by muse, mutect2, varscan2
- ATM | c.6910G>C p.E2304Q | Missense Mutation (SNP) | VAF 40/40 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as CX068644, COSV53739193; called by muse, mutect2, varscan2
- BEGAIN | c.460G>A p.V154M | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as rs779124211; called by muse, mutect2
- BRINP3 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); catalogued as rs1379453749, COSV66524468; called by muse, mutect2, varscan2
- CD276 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as rs773066542, COSV59203720; called by muse, mutect2, varscan2
- CDH8 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 104/196 reads (53%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs144033516; called by muse, mutect2, varscan2
- CEP83 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767118598, COSV60409300; called by muse, mutect2, varscan2
- COL3A1 | c.3191G>A p.R1064K | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV100483909; called by muse, mutect2, varscan2
- CRACD | c.701A>C p.K234T | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV51714737; called by muse, mutect2, varscan2
- DUSP2 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.736); catalogued as rs1373855943; called by muse, mutect2, varscan2
- FSIP2 | c.20134T>A p.F6712I | Missense Mutation (SNP) | VAF 68/71 reads (96%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs928129379, COSV58085601; called by muse, mutect2, varscan2
- GPR139 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 56/100 reads (56%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as rs760723072, COSV58503347; called by muse, mutect2, varscan2
- IGHD2-2 | c.30C>G p.C10W | Missense Mutation (SNP) | VAF 20/21 reads (95%) | catalogued as rs373145986; called by muse, mutect2, varscan2
- IGHV2-70 | c.76T>C p.S26P | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs374458740; called by muse, varscan2
- IGHV2-70D | c.148A>G p.T50A | Missense Mutation (SNP) | VAF 38/41 reads (93%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs1292545219; called by muse, varscan2
- IGLL5 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 15/15 reads (100%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.08); catalogued as rs538723125, COSV73251010, COSV73251135, COSV73251305; called by muse, mutect2, varscan2
- IGLV3-1 | c.47-1G>A p.X16_splice | Splice Site (SNP) | VAF 46/50 reads (92%) | catalogued as rs773087667; called by muse, varscan2
- IGLV3-1 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 42/44 reads (95%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs763621186; called by muse, varscan2
- ITGAL | c.3195C>A p.F1065L | Missense Mutation (SNP) | VAF 24/345 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.472); catalogued as COSV100776358; called by muse, mutect2
- LATS2 | c.1097C>T p.S366F | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.094); catalogued as rs1318715498, COSV66877250; called by muse, mutect2, varscan2
- MEP1A | c.1418C>G p.P473R | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100042793; called by muse, mutect2
- MYH3 | c.2459G>A p.R820H | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs1220315724, COSV56865499; called by muse, mutect2, varscan2
- NR2E3 | c.1024G>A p.V342I | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.555); catalogued as rs757270261; called by muse, mutect2, varscan2
- NWD1 | c.2384G>A p.R795H | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.572); catalogued as rs771113312, COSV60341721; called by muse, mutect2, varscan2
- PCDHA9 | c.1963G>A p.G655R | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100970042; called by muse, mutect2, varscan2
- PHTF2 | c.1487G>A p.G496E (on ENST00000248550 / NM_001366089.1; = p.G458E on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/334 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV50344313; called by muse, mutect2
- RALGAPB | c.1735G>A p.D579N | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99486020; called by muse, mutect2, varscan2
- VWF | c.5369C>T p.P1790L | Missense Mutation (SNP) | VAF 80/149 reads (54%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs551649729, COSV54624764; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZBTB46 | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs772039287, COSV99829830; called by muse, mutect2, varscan2
- ZNF304 | c.1031A>G p.Y344C | Missense Mutation (SNP) | VAF 11/184 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs1220267257, COSV99988918; called by muse, mutect2
- ZNF609 | c.2564G>C p.G855A | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV100442016, COSV58590106; called by muse, mutect2, varscan2
- APOH | c.878G>A p.G293D | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ARID1A | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.878); called by muse, mutect2
- ASCC3 | c.125A>T p.D42V | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ASXL3 | c.4911C>A p.S1637R | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CATSPERD | c.1436A>C p.K479T | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH23 | c.2509C>T p.H837Y | Missense Mutation (SNP) | VAF 48/272 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- CDKN2AIP | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- CYP1A2 | c.95G>T p.R32M | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.789); called by muse, mutect2
- DGAT2L6 | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 48/48 reads (100%) | SIFT tolerated (0.2); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- DIPK1C | c.652C>G p.H218D | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- DPP6 | c.32A>T p.K11M | Missense Mutation (SNP) | VAF 54/269 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ECPAS | c.5214dup p.Q1739Sfs*14 | Frame Shift Ins (INS) | VAF 106/219 reads (48%) | called by mutect2, pindel, varscan2
- EIPR1 | c.982G>C p.E328Q | Missense Mutation (SNP) | VAF 20/20 reads (100%) | SIFT tolerated (0.23); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- FAT4 | c.3322T>G p.Y1108D | Missense Mutation (SNP) | VAF 73/145 reads (50%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- FBXW9 | c.522T>C p.G174= (on ENST00000587955; = p.G184= on NM_032301.3) | Splice Region (SNP) | VAF 46/168 reads (27%) | called by muse, mutect2
- FBXW9 | c.349C>T p.H117Y | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- FBXW9 | c.30T>A p.D10E | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- GCC2 | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 33/312 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- HNRNPM | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2
- HSPA12A | c.1982C>A p.A661D | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- IGHV2-70D | c.241A>G p.S81G | Missense Mutation (SNP) | VAF 36/43 reads (84%) | SIFT tolerated (0.05); PolyPhen benign (0.165); called by muse, varscan2
- IGHV2-70D | c.217G>C p.D73H | Missense Mutation (SNP) | VAF 27/30 reads (90%) | SIFT tolerated (0.48); PolyPhen benign (0.194); called by muse, varscan2
- IKZF3 | c.1201_1204del p.Y401Sfs*17 | Frame Shift Del (DEL) | VAF 42/131 reads (32%) | called by mutect2, pindel, varscan2
- ITGB2 | c.2104C>T p.Q702* (on ENST00000302347; = p.Q678* on NM_000211.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- KIF13A | c.685A>C p.I229L | Missense Mutation (SNP) | VAF 79/156 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LENG8 | c.1163G>T p.G388V | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.802); called by muse, varscan2
- LRFN5 | c.182A>G p.N61S | Missense Mutation (SNP) | VAF 105/187 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MCL1 | c.745G>C p.V249L | Missense Mutation (SNP) | VAF 65/126 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- MGAT4C | c.821A>T p.H274L | Missense Mutation (SNP) | VAF 99/188 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- NCF2 | c.356T>G p.F119C | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- NCR2 | c.758T>C p.V253A | Missense Mutation (SNP) | VAF 14/378 reads (4%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.024); called by muse, mutect2
- NCR2 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 15/373 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.112); called by muse, mutect2
- OR2A25 | c.593T>A p.V198D | Missense Mutation (SNP) | VAF 11/176 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); called by muse, mutect2
- PKD1L3 | c.5153C>A p.T1718K | Missense Mutation (SNP) | VAF 15/221 reads (7%) | SIFT tolerated (0.9); PolyPhen benign (0.014); called by muse, mutect2
- PKP2 | c.489C>G p.H163Q | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRPF39 | c.718T>C p.Y240H | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRR27 | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RALGPS2 | c.838C>G p.L280V | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- RERE | c.4219G>C p.A1407P | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RNF213 | c.3470T>C p.V1157A | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- SCGB2B2 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- SDHAF4 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC17A2 | c.359A>C p.K120T | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- SNX30 | c.1001C>G p.S334C | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- TBC1D4 | c.3566C>T p.S1189F | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2
- TESPA1 | c.1177C>T p.H393Y (on ENST00000316577 / NM_001098815.3; = p.H255Y on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/124 reads (59%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- TMTC1 | c.562G>A p.D188N (on ENST00000539277 / NM_001193451.2; = p.D80N on NM_175861.3) | Missense Mutation (SNP) | VAF 50/225 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TXNRD1 | c.1678G>C p.E560Q (on ENST00000525566 / NM_001093771.3; = p.E462Q on NM_003330.4) | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- UNC5C | c.2641T>G p.Y881D | Missense Mutation (SNP) | VAF 60/120 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF618 | c.1676G>T p.G559V (on ENST00000374126 / NM_001318042.2; = p.G466V on NM_133374.2) | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABCB4 | c.2101C>T p.L701= | Silent (SNP) | VAF 8/109 reads (7%) | catalogued as COSV99710069; called by muse, mutect2
- AMDHD2 | c.1026C>T p.F342= (on ENST00000293971 / NM_001330449.2; = p.F372= on NM_015944.4) | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as rs781177091; called by muse, mutect2, varscan2
- C4BPA | c.1383C>T p.V461= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as rs773326982, COSV65537940; called by muse, mutect2, varscan2
- CASD1 | c.1494T>C p.N498= | Silent (SNP) | VAF 37/81 reads (46%) | called by muse, mutect2, varscan2
- CYTIP | c.96C>T p.G32= | Silent (SNP) | VAF 55/122 reads (45%) | called by muse, mutect2, varscan2
- ELANE | c.519C>T p.N173= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs200393776; ClinVar: likely benign; called by muse, mutect2, varscan2
- GSE1 | c.2730G>A p.P910= | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as rs768882973; called by muse, mutect2, varscan2
- H2BC7 | c.126G>A p.V42= | Silent (SNP) | VAF 98/185 reads (53%) | catalogued as rs576787074; called by muse, mutect2, varscan2
- HNRNPM | c.99T>G p.A33= | Silent (SNP) | VAF 22/80 reads (28%) | called by muse, mutect2, varscan2
- IGHV1-69 | c.162C>T p.S54= | Silent (SNP) | VAF 56/100 reads (56%) | catalogued as rs782296104; called by muse, varscan2
- IGHV2-70 | c.96A>G p.K32= | Silent (SNP) | VAF 42/69 reads (61%) | catalogued as rs368957766; called by muse, varscan2
- IGKV1-5 | c.180G>A p.Q60= | Silent (SNP) | VAF 92/116 reads (79%) | catalogued as rs567604618; called by muse, varscan2
- JPH4 | c.846C>T p.Y282= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as rs1566680117; called by muse, mutect2, varscan2
- JUNB | c.561C>T p.S187= | Silent (SNP) | VAF 142/302 reads (47%) | called by muse, mutect2, varscan2
- OR4D2 | c.819C>T p.I273= | Silent (SNP) | VAF 23/247 reads (9%) | catalogued as rs754786366; called by muse, mutect2, varscan2
- PRKCI | c.39G>A p.T13= | Silent (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- PTGIR | c.843C>T p.Y281= | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as rs778174017, COSV52191410; called by muse, mutect2, varscan2
- RSF1 | c.3030G>A p.R1010= | Silent (SNP) | VAF 7/101 reads (7%) | called by muse, mutect2
- SALL3 | c.2100G>A p.T700= | Silent (SNP) | VAF 108/186 reads (58%) | catalogued as rs1422558024, COSV73306636, COSV73306773; called by muse, mutect2, varscan2
- SDR16C5 | c.534A>T p.S178= | Silent (SNP) | VAF 7/135 reads (5%) | called by muse, mutect2
- TMC4 | c.1086C>T p.A362= (on ENST00000617472 / NM_001145303.3; = p.A356= on NM_144686.4) | Silent (SNP) | VAF 26/61 reads (43%) | called by muse, mutect2, varscan2
- TRPC5 | c.1641C>T p.I547= | Silent (SNP) | VAF 71/78 reads (91%) | catalogued as rs756533089, COSV53283740; called by muse, mutect2, varscan2
- ZDHHC14 | c.345C>T p.S115= | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as rs748528510, COSV100702387; called by muse, mutect2, varscan2
- ZNF334 | c.486T>C p.P162= | Silent (SNP) | VAF 53/104 reads (51%) | called by muse, mutect2, varscan2
- AC020688.1 | chr8:127087859 T>G | 5'Flank (SNP) | VAF 60/161 reads (37%) | called by muse, mutect2, varscan2
- ACSL4 | c.*1815del | 3'UTR (DEL) | VAF 42/44 reads (95%) | catalogued as rs1309631021; called by mutect2, varscan2
- ACVR2A | c.*808G>A | 3'UTR (SNP) | VAF 10/83 reads (12%) | called by muse, mutect2, varscan2
- ALG2 | c.*243C>T | 3'UTR (SNP) | VAF 77/169 reads (46%) | catalogued as rs1164365070; called by muse, mutect2, varscan2
- ANO3 | c.591+166T>G | Intron (SNP) | VAF 28/70 reads (40%) | called by muse, mutect2, varscan2
- ARMC8 | c.*2196T>A | 3'UTR (SNP) | VAF 7/105 reads (7%) | called by muse, mutect2
- ATP4A | c.-5G>A | 5'UTR (SNP) | VAF 8/111 reads (7%) | catalogued as rs933437522; called by muse, mutect2
- BCL2 | c.585+43T>C | Intron (SNP) | VAF 31/63 reads (49%) | called by muse, mutect2, varscan2
- BDP1 | c.*1545del | 3'UTR (DEL) | VAF 59/147 reads (40%) | called by mutect2, pindel, varscan2
- BNIP2 | c.*2611A>G | 3'UTR (SNP) | VAF 33/63 reads (52%) | called by muse, mutect2, varscan2
- C1QL3 | c.*305T>C | 3'UTR (SNP) | VAF 35/87 reads (40%) | catalogued as rs1315898794; called by muse, mutect2, varscan2
- C3orf33 | c.*106G>A | 3'UTR (SNP) | VAF 115/211 reads (55%) | called by muse, mutect2, varscan2
- CACNA1E | c.*5982G>C | 3'UTR (SNP) | VAF 8/164 reads (5%) | catalogued as rs1260419940; called by muse, mutect2
- CCDC120 | c.-21C>T | 5'UTR (SNP) | VAF 23/234 reads (10%) | called by muse, mutect2
- CCND1 | c.*2101C>T | 3'UTR (SNP) | VAF 9/124 reads (7%) | called by muse, mutect2
- CCNL1 | c.379-70T>C | Intron (SNP) | VAF 20/46 reads (43%) | called by muse, mutect2
- CDC42BPA | chr1:227317851 C>T | 5'Flank (SNP) | VAF 47/99 reads (47%) | called by muse, mutect2, varscan2
- CDH7 | chr18:65884376 G>A | 3'Flank (SNP) | VAF 59/109 reads (54%) | called by muse, mutect2, varscan2
- CEP44 | c.*478C>T | 3'UTR (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- CHIC1 | c.*1083G>C | 3'UTR (SNP) | VAF 62/64 reads (97%) | called by muse, mutect2, varscan2
- COL14A1 | c.5312-491C>T | Intron (SNP) | VAF 29/509 reads (6%) | called by muse, mutect2
- COX18 | c.*2037A>C | 3'UTR (SNP) | VAF 26/68 reads (38%) | called by muse, varscan2
- CPXCR1 | c.*191C>G | 3'UTR (SNP) | VAF 45/45 reads (100%) | called by muse, mutect2, varscan2
- CTBP2 | c.*2295T>C | 3'UTR (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2, varscan2
- CTNNA2 | c.102+35980G>T | Intron (SNP) | VAF 112/235 reads (48%) | catalogued as rs1208087820; called by muse, mutect2, varscan2
- CYP19A1 | c.*2184A>G | 3'UTR (SNP) | VAF 16/75 reads (21%) | called by muse, mutect2
- DCAF4L2 | c.*1514C>A | 3'UTR (SNP) | VAF 20/288 reads (7%) | called by muse, mutect2
- DENND5B | c.*3642dup | 3'UTR (INS) | VAF 14/126 reads (11%) | catalogued as rs1406423564; called by mutect2, varscan2
- DNAJC2 | chr7:103344824 C>T | 5'Flank (SNP) | VAF 75/130 reads (58%) | called by muse, mutect2, varscan2
- DNMT3B | c.*1009G>A | 3'UTR (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2, varscan2
- DPY19L2 | c.*413G>A | 3'UTR (SNP) | VAF 24/536 reads (4%) | called by muse, mutect2
- DRC7 | c.1975-73G>T | Intron (SNP) | VAF 6/60 reads (10%) | called by muse, varscan2
- DTX1 | c.-308C>T | 5'UTR (SNP) | VAF 30/84 reads (36%) | called by muse, varscan2
- DTX1 | c.-307C>T | 5'UTR (SNP) | VAF 32/84 reads (38%) | catalogued as COSV57496040; called by muse, varscan2
- DTX1 | c.-287A>C | 5'UTR (SNP) | VAF 58/102 reads (57%) | called by muse, varscan2
- ECM2 | c.481+241C>T | Intron (SNP) | VAF 94/98 reads (96%) | called by muse, mutect2, varscan2
- EIPR1 | chr2:3188928 G>A | 3'Flank (SNP) | VAF 8/8 reads (100%) | called by muse, varscan2
- EPHB2 | c.*450G>A | 3'UTR (SNP) | VAF 62/124 reads (50%) | called by muse, mutect2, varscan2
- ESR1 | c.*2672G>T | 3'UTR (SNP) | VAF 35/65 reads (54%) | called by muse, mutect2, varscan2
- EVX1 | chr7:27242660 G>A | 5'Flank (SNP) | VAF 10/128 reads (8%) | catalogued as rs967508252; called by muse, mutect2
- EXPH5 | c.*2971T>C | 3'UTR (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2, varscan2
- EYS | c.1766+5657A>G | Intron (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- EZR | c.12+85C>T | Intron (SNP) | VAF 33/71 reads (46%) | called by muse, mutect2, varscan2
- FAM167A | c.381+5539C>T | Intron (SNP) | VAF 10/200 reads (5%) | called by muse, mutect2
- FAM204A | chr10:118306381 C>T | 3'Flank (SNP) | VAF 41/111 reads (37%) | catalogued as rs769089925; called by muse, mutect2, varscan2
- FIP1L1 | c.-12C>T | 5'UTR (SNP) | VAF 54/99 reads (55%) | catalogued as rs746607373; called by muse, mutect2, varscan2
- FOLH1B | n.1238T>G | RNA (SNP) | VAF 37/42 reads (88%) | called by muse, mutect2, varscan2
- FTO | c.*6097G>A | 3'UTR (SNP) | VAF 6/73 reads (8%) | called by muse, mutect2
- GAS2L2 | c.*278C>T | 3'UTR (SNP) | VAF 9/76 reads (12%) | called by muse, mutect2, varscan2
- GBP4 | c.*219T>C | 3'UTR (SNP) | VAF 33/33 reads (100%) | called by muse, mutect2, varscan2
- GLI3 | c.*3190G>A | 3'UTR (SNP) | VAF 52/119 reads (44%) | catalogued as rs1182422396; called by muse, mutect2, varscan2
- GNG7 | c.-78+2844C>T | Intron (SNP) | VAF 75/258 reads (29%) | catalogued as rs1431587863; called by muse, varscan2
- GNGT1 | c.97-1205G>A | Intron (SNP) | VAF 178/383 reads (46%) | called by muse, mutect2, varscan2
- GPAT4 | c.*1681G>A | 3'UTR (SNP) | VAF 24/62 reads (39%) | called by muse, mutect2, varscan2
- GPAT4 | c.*1682G>A | 3'UTR (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2, varscan2
- GPR31 | c.*528A>G | 3'UTR (SNP) | VAF 15/163 reads (9%) | called by muse, mutect2
- GRAMD1B | c.24-16765A>G | Intron (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- GSTZ1 | c.16-342C>T | Intron (SNP) | VAF 4/92 reads (4%) | catalogued as rs934815817; called by muse, mutect2
- H2AC11 | c.*94C>G | 3'UTR (SNP) | VAF 107/205 reads (52%) | called by muse, mutect2, varscan2
- HNF4G | chr8:75566041 del A | 3'Flank (DEL) | VAF 25/72 reads (35%) | catalogued as rs577669664; called by mutect2, varscan2
- HS2ST1 | c.*748A>G | 3'UTR (SNP) | VAF 52/53 reads (98%) | called by muse, mutect2, varscan2
- HSPA4L | c.-139G>A | 5'UTR (SNP) | VAF 7/129 reads (5%) | called by muse, mutect2
- INSIG2 | c.*180T>C | 3'UTR (SNP) | VAF 10/148 reads (7%) | called by muse, mutect2
- KIAA1109 | c.2794-66T>G | Intron (SNP) | VAF 50/94 reads (53%) | called by muse, mutect2, varscan2
- LGR4 | c.*988T>G | 3'UTR (SNP) | VAF 26/87 reads (30%) | called by muse, mutect2, varscan2
- LRRC38 | c.*330G>C | 3'UTR (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- LTN1 | c.*832G>C | 3'UTR (SNP) | VAF 62/129 reads (48%) | called by muse, mutect2, varscan2
- LTN1 | c.*497G>A | 3'UTR (SNP) | VAF 50/94 reads (53%) | catalogued as rs1472735183; called by muse, mutect2, varscan2
- MACROD2 | chr20:16051795 G>A | 3'Flank (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
- MAP1B | c.*3908C>A | 3'UTR (SNP) | VAF 61/93 reads (66%) | called by muse, mutect2, varscan2
- MATR3 | c.-178+78G>A | Intron (SNP) | VAF 13/33 reads (39%) | called by muse, mutect2, varscan2
- MITD1 | c.-50G>C | 5'UTR (SNP) | VAF 42/86 reads (49%) | called by muse, mutect2, varscan2
- MMRN1 | chr4:89894749 C>A | 5'Flank (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- MYO19 | c.1354-34G>A | Intron (SNP) | VAF 8/15 reads (53%) | called by muse, mutect2, varscan2
- MYO1E | c.-38C>A | 5'UTR (SNP) | VAF 32/50 reads (64%) | catalogued as rs1001549188; called by muse, mutect2, varscan2
- NCOA3 | c.*1493C>T | 3'UTR (SNP) | VAF 9/43 reads (21%) | called by muse, mutect2, varscan2
- NECAP2 | c.*406C>T | 3'UTR (SNP) | VAF 77/144 reads (53%) | catalogued as rs140844530; called by muse, mutect2, varscan2
- NID1 | c.*312G>C | 3'UTR (SNP) | VAF 13/100 reads (13%) | called by muse, mutect2, varscan2
- NLGN1 | c.*4443T>G | 3'UTR (SNP) | VAF 48/93 reads (52%) | called by muse, mutect2, varscan2
- OR7D1P | n.575C>A | RNA (SNP) | VAF 89/350 reads (25%) | called by muse, mutect2, varscan2
- PCDH10 | c.*213T>A | 3'UTR (SNP) | VAF 48/108 reads (44%) | called by muse, mutect2, varscan2
- PCNX2 | c.6241-569G>A | Intron (SNP) | VAF 31/78 reads (40%) | called by muse, mutect2, varscan2
- PCNX2 | c.3946+184G>A | Intron (SNP) | VAF 27/55 reads (49%) | called by muse, mutect2, varscan2
- PDE4D | c.*4795G>A | 3'UTR (SNP) | VAF 52/108 reads (48%) | called by muse, mutect2, varscan2
- PDGFRB | c.*672A>G | 3'UTR (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
- PDZD8 | c.*5737C>T | 3'UTR (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- PKIB | c.*45G>A | 3'UTR (SNP) | VAF 10/381 reads (3%) | called by muse, mutect2
- PLD1 | c.-32+17569G>T | Intron (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2
- PNPLA8 | c.*383G>A | 3'UTR (SNP) | VAF 33/71 reads (46%) | called by muse, mutect2, varscan2
- PNRC1 | c.-8C>T | 5'UTR (SNP) | VAF 188/395 reads (48%) | catalogued as rs1299190065; called by muse, mutect2, varscan2
- POU3F4 | c.*182C>T | 3'UTR (SNP) | VAF 19/24 reads (79%) | called by muse, mutect2, varscan2
- PRMT8 | c.-49C>G | 5'UTR (SNP) | VAF 24/430 reads (6%) | called by muse, mutect2
- PTPRD | c.*984C>A | 3'UTR (SNP) | VAF 49/91 reads (54%) | called by muse, mutect2, varscan2
- PVR | c.-15C>A | 5'UTR (SNP) | VAF 22/40 reads (55%) | called by muse, mutect2, varscan2
- QSOX1 | c.*5989_*5998del | 3'UTR (DEL) | VAF 12/25 reads (48%) | called by mutect2, pindel
- RAB3C | c.*6712G>A | 3'UTR (SNP) | VAF 8/112 reads (7%) | catalogued as rs1463297477; called by muse, mutect2
- RABGGTA | c.*45A>G | 3'UTR (SNP) | VAF 38/100 reads (38%) | called by muse, mutect2, varscan2
- RBBP9 | c.*2576C>T | 3'UTR (SNP) | VAF 8/46 reads (17%) | catalogued as rs1027907551; called by muse, mutect2
- RNF167 | c.671-53C>A | Intron (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- RPS6KA5 | c.*1105G>C | 3'UTR (SNP) | VAF 5/54 reads (9%) | called by muse, mutect2
- RTN4RL2 | c.-88C>G | 5'UTR (SNP) | VAF 4/9 reads (44%) | called by muse, mutect2, varscan2
- SAMD4A | c.-58G>A | 5'UTR (SNP) | VAF 24/46 reads (52%) | called by muse, mutect2
- SEMA6A | c.1730-1022A>T | Intron (SNP) | VAF 7/70 reads (10%) | called by muse, mutect2
- SH2D4A | c.*965A>G | 3'UTR (SNP) | VAF 31/65 reads (48%) | called by muse, mutect2, varscan2
- SHISA7 | c.*1600C>G | 3'UTR (SNP) | VAF 23/56 reads (41%) | called by muse, mutect2, varscan2
- SLF1 | c.*308A>T | 3'UTR (SNP) | VAF 48/106 reads (45%) | called by muse, mutect2, varscan2
- SPICE1 | c.2323+70T>C | Intron (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2
- STARD10 | c.*49C>T | 3'UTR (SNP) | VAF 3/38 reads (8%) | catalogued as rs1341999184; called by muse, mutect2
- TCF3 | c.1823-501T>A | Intron (SNP) | VAF 116/191 reads (61%) | catalogued as COSV104369182, COSV53651144; called by muse, mutect2, varscan2
- TMPRSS3 | c.952+69G>A | Intron (SNP) | VAF 18/269 reads (7%) | called by muse, mutect2
- TNPO2 | c.*1935C>A | 3'UTR (SNP) | VAF 22/74 reads (30%) | called by muse, varscan2
- TNPO2 | c.*1859C>T | 3'UTR (SNP) | VAF 27/77 reads (35%) | called by muse, varscan2
- TNPO2 | c.*1775C>A | 3'UTR (SNP) | VAF 9/21 reads (43%) | called by muse, varscan2
- TRA2A | c.838+38T>A | Intron (SNP) | VAF 14/27 reads (52%) | called by muse, mutect2, varscan2
- TRPV6 | c.470-37G>A | Intron (SNP) | VAF 15/239 reads (6%) | called by muse, mutect2
- TUSC3 | c.426+35A>C | Intron (SNP) | VAF 38/70 reads (54%) | called by muse, varscan2
- TXLNB | c.*2155T>C | 3'UTR (SNP) | VAF 63/286 reads (22%) | called by muse, mutect2, varscan2
- VDR | c.*1222_*1223del | 3'UTR (DEL) | VAF 75/168 reads (45%) | called by mutect2, pindel, varscan2
- VSTM2A | c.634+1673G>A | Intron (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- WAC | c.*69dup | 3'UTR (INS) | VAF 120/297 reads (40%) | called by mutect2, pindel, varscan2
- ZBTB40 | c.*95G>A | 3'UTR (SNP) | VAF 50/109 reads (46%) | catalogued as rs989417614, COSV100988822; called by muse, mutect2, varscan2
- ZDHHC22 | c.*760G>T | 3'UTR (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
